Gene-level copy-number profile of tumor specimen HCM-CSHL-0811-C55-01A from HCMI case HCM-CSHL-0811-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G3.
Specimen HCM-CSHL-0811-C55-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e08f4bd9-ac16-4ee5-baf9-6a19c52e9c78.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0811-C55-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/1412e96e-84fb-4e44-9129-babaabfd64d8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 326; copy number 2: 13,080; copy number 3: 22,019; copy number 4: 17,196; copy number 5: 3,707; copy number 6: 964; copy number 7: 592; copy number 8: 9; copy number 9: 40; copy number 10: 15; copy number 11: 23; copy number 12: 110; copy number 13: 25; copy number 14: 17; copy number 15: 91; copy number 16: 53; copy number 17: 12; copy number 18: 7; copy number 19: 75; copy number 20: 11; copy number 23: 1; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:10,486,125–10,503,558, 2 genes: KEAP1, AC011461.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,082 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,638,745–9,746,869, 4 genes, copy number 8–9 (within-gene range 5–9): AC082651.1, AC082651.4, RNU4-73P, AC082651.2.
- chr2:90,121,786–90,154,574, 2 genes, copy number 8: IGKV2D-14, IGKV1D-13.
- chr2:90,172,802–90,367,699, 10 genes, copy number 7–11: IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr5:134,114,681–134,151,865, 1 gene, copy number 7 (within-gene range 3–7): TCF7.
- chr6:32,659,467–32,668,383, 1 gene, copy number 7 (within-gene range 4–7): HLA-DQB1.
- chr6:32,706,124–33,009,591, 22 genes, copy number 7: MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA.
- chr10:14,061–29,318,328, 474 genes, copy number 7 (broad region; genes not listed).
- chr13:98,610,292–98,641,239, 3 genes, copy number 10: NUS1P4, CYCSP35, CALM2P4.
- chr14:18,333,726–18,419,273, 4 genes, copy number 7–9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:18,634,955–18,637,421, 2 genes, copy number 11 (within-gene range 6–11): CR383656.1, CR383656.12.
- chr14:18,709,478–18,712,643, 1 gene, copy number 11: NF1P10.
- chr15:94,168,349–94,168,751, 1 gene, copy number 7: H3P40.
- chr16:46,469,341–46,851,254, 17 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2.
- chr17:20,185,082–22,070,538, 86 genes, copy number 12–18 (within-gene range 2–18) (broad region; genes not listed).
- chr17:31,851,871–32,253,374, 21 genes, copy number 7–8: COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2.
- chr19:29,205,320–39,182,816, 361 genes, copy number 9–27 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:8,701,461–9,914,846, 26 genes, copy number 7: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.
- chr21:10,328,411–13,120,807, 16 genes, copy number 9: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:18,773,665–18,843,399, 2 genes, copy number 16 (within-gene range 2–16): GGT3P, AC008132.2.
- chr22:21,141,624–21,142,371, 1 gene, copy number 12: E2F6P2.
- chr22:21,466,423–21,471,269, 1 gene, copy number 8: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 326. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
